Somatic mutation profile of tumor specimen TARGET-30-PARFWB-01A (aliquot TARGET-30-PARFWB-01A-01D) from TARGET case TARGET-30-PARFWB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Age at diagnosis: 4.3 years (1,555 days).
Specimen TARGET-30-PARFWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99c324fa-97a3-4b01-83d2-4441fcc027b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARFWB-10A (Blood Derived Normal), aliquot TARGET-30-PARFWB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7018852-7dd4-4cc7-87ba-19abaa99597c

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Splice Region 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6563G>A p.R2188Q | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64879508, COSV64879971; called by muse, mutect2, varscan2
- COL5A3 | c.3684T>G p.I1228M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV53414725; called by muse, mutect2
- CSMD3 | c.1198A>T p.S400C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.156); catalogued as COSV52243836; called by muse, mutect2, varscan2
- DUSP2 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56620381; called by muse, mutect2, varscan2
- IDE | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as rs759744308, COSV56425271; called by muse, mutect2, varscan2
- KCNA5 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV52904287; called by muse, mutect2, varscan2
- MTERF1 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61098718; called by muse, mutect2, varscan2
- OR5B3 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV58678016, COSV58678032; called by muse, mutect2, varscan2
- POP4 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV55676897; called by muse, mutect2, varscan2
- PRAMEF12 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63216000; called by muse, mutect2, varscan2
- RIMS2 | c.1491G>C p.K497N (on ENST00000666250 / NM_001348490.2; = p.K305N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV51700314; called by muse, mutect2, varscan2
- RNF148 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478469716; called by muse, mutect2
- SPINK5 | c.3189C>T p.D1063= | Splice Region (SNP) | VAF 43/121 reads (36%) | catalogued as rs200751535; ClinVar: likely benign; called by muse, mutect2, varscan2
- TET1 | c.4279C>A p.R1427= | Splice Region (SNP) | VAF 60/163 reads (37%) | catalogued as COSV101018562, COSV65386876; called by muse, mutect2, varscan2
- TM9SF3 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV64457947; called by muse, mutect2, varscan2
- TNXB | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64483293; called by muse, mutect2, varscan2
- ZNF652 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV62947888; called by muse, mutect2, varscan2
- JADE1 | c.1588_1621+9del p.X530_splice | Splice Site (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- APOBEC3D | c.90G>T p.R30= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- DRP2 | c.1137C>T p.C379= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as COSV65811053; called by muse, mutect2, varscan2
- DYNC1H1 | c.13914G>A p.R4638= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV64139354; called by muse, mutect2, varscan2
- OSBPL5 | c.1626C>A p.I542= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV55143675; called by muse, mutect2, varscan2
- RTN3 | c.1638G>A p.E546= (on ENST00000377819 / NM_001265589.2; = p.E527= on NM_201428.3) | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
